Somatic mutation profile of tumor specimen TCGA-74-6575-01A (aliquot TCGA-74-6575-01A-11D-1845-08) from TCGA case TCGA-74-6575, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.4 years (26,827 days).
Specimen TCGA-74-6575-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15aaa2cd-8767-4cd4-8ce8-c61040bb02f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-74-6575-10A (Blood Derived Normal), aliquot TCGA-74-6575-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35d63751-7306-4f81-83ff-2d5c37d6ee12

The open-access MAF lists 98 somatic variants for this specimen: 68 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 27, Nonsense Mutation 3, Frame Shift Ins 3, Frame Shift Del 3, Splice Region 3, Splice Site 2, Intron 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514637, CM122747, COSV62097556; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 26/157 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758303489, CM073403, COSV56389122, COSV56441978; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AKAP8L | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs750798229, COSV68473754; called by muse, mutect2, varscan2
- ALDH1A3 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60902097; called by muse, mutect2, varscan2
- ATRX | c.4112G>C p.R1371T | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV64878641; called by muse, mutect2, varscan2
- BSN | c.7522G>A p.A2508T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56521198; called by muse, mutect2, varscan2
- CADPS | c.3121C>A p.Q1041K | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV51887071; called by muse, mutect2, varscan2
- CD1E | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs750925859, COSV63770860; called by muse, mutect2, varscan2
- CDKL5 | c.2715C>T p.D905= | Splice Region (SNP) | VAF 16/123 reads (13%) | catalogued as rs201714912, COSV66106173; called by muse, mutect2, varscan2
- CHD1 | c.4882C>T p.H1628Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV52336498; called by muse, mutect2, varscan2
- COL1A2 | c.1544T>A p.L515H | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.749); catalogued as COSV51960466; called by muse, mutect2, varscan2
- CORO7 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs755060334, COSV52031377; called by muse, mutect2
- CRAT | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs377397536; called by muse, mutect2, varscan2
- CSF2RA | c.342A>G p.S114= | Splice Region (SNP) | VAF 12/326 reads (4%) | catalogued as COSV62625210; called by muse, mutect2
- DNAH11 | c.1258G>T p.V420L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.044); catalogued as COSV60962797; called by muse, mutect2, varscan2
- DSC2 | c.972A>T p.K324N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV51866272; called by muse, mutect2, varscan2
- ECT2 | c.1642C>G p.P548A (on ENST00000392692 / NM_001349098.2; = p.P517A on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV51690322; called by muse, mutect2, varscan2
- GABRA6 | c.1249A>G p.I417V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as rs554830106, COSV50884250; called by muse, mutect2, varscan2
- GOLGA3 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs772586724, COSV52635008; called by muse, mutect2, varscan2
- GPR32 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV54514889; called by muse, mutect2, varscan2
- GRIN2B | c.2466C>G p.F822L | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74206485; called by muse, mutect2
- HYAL4 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56139064; called by muse, mutect2, varscan2
- IGF2R | c.4570+1G>T p.X1524_splice | Splice Site (SNP) | VAF 23/90 reads (26%) | catalogued as COSV100808058; called by muse, mutect2, varscan2
- KSR2 | c.1486C>G p.Q496E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.135); catalogued as COSV56675851; called by muse, mutect2
- LANCL2 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs375166275; called by muse, mutect2, varscan2
- LCN6 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.559); catalogued as rs753293850, COSV57910770, COSV57910822; called by muse, mutect2, varscan2
- LILRB3 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as COSV54435929; called by muse, varscan2
- MCTP1 | c.2839A>T p.K947* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV56521551; called by muse, mutect2, varscan2
- MORC1 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.131); catalogued as rs747344612, COSV51722959; called by muse, mutect2, varscan2
- NLRP13 | c.3122A>T p.K1041I | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.418); catalogued as COSV61620140, COSV61622528; called by muse, mutect2
- NPC1L1 | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV56926580; called by muse, mutect2, varscan2
- NRXN3 | c.2420G>A p.R807H (on ENST00000335750 / NM_001330195.2; = p.R434H on NM_004796.6) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV59758617; called by muse, mutect2, varscan2
- NYAP2 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774975681, COSV56009066; called by muse, mutect2, varscan2
- OR14A16 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV62926515; called by muse, mutect2, varscan2
- OR4M1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs148303756; called by muse, mutect2, varscan2
- PAN3 | c.968T>C p.M323T | Missense Mutation (SNP) | VAF 97/314 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV66709401; called by muse, mutect2, varscan2
- PLAT | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564988743, COSV54274282; called by muse, mutect2, varscan2
- POU3F4 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64538777, COSV64539758; called by muse, mutect2, varscan2
- PRDM9 | c.1553T>A p.I518N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.416); catalogued as COSV57008341; called by muse, varscan2
- RAB11FIP4 | c.1118C>A p.T373K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV57930254; called by muse, mutect2, varscan2
- RP1 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886062989, COSV55112474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERINC2 | c.374G>A p.R125Q (on ENST00000373709 / NM_178865.5; = p.R129Q on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs782665542, COSV65490860; called by muse, mutect2, varscan2
- SHCBP1L | c.1126A>T p.R376* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV62355542; called by muse, mutect2, varscan2
- SOS1 | c.1399T>G p.L467V | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.864); catalogued as COSV67676137; called by muse, mutect2, varscan2
- SPEF2 | c.3208T>A p.F1070I | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV61549570; called by muse, mutect2
- SPTA1 | c.3473G>A p.R1158Q | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as rs765768719, COSV63752963; called by muse, mutect2, varscan2
- TAS2R10 | c.473A>G p.N158S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.035); catalogued as COSV53701221; called by muse, mutect2, varscan2
- TGFA | c.62A>G p.Q21R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.888); catalogued as COSV54914429; called by muse, mutect2, varscan2
- TLR7 | c.2810A>T p.Q937L | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV66124650; called by muse, mutect2, varscan2
- TP63 | c.581A>C p.Y194S | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53200631, COSV53210172; called by muse, mutect2
- TTC39B | c.480C>G p.P160= | Splice Region (SNP) | VAF 8/44 reads (18%) | catalogued as rs1428045232, COSV52607310, COSV52611702; called by muse, mutect2, varscan2
- TTN | c.85315G>A p.A28439T (on ENST00000591111; = p.A21015T on NM_003319.4) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | PolyPhen probably damaging (0.939); catalogued as rs753375022, COSV60150397; called by muse, mutect2, varscan2
- TTN | c.60457G>A p.V20153I (on ENST00000591111; = p.V12729I on NM_003319.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | PolyPhen benign (0.007); catalogued as rs373848128, COSV60047592; called by muse, mutect2, varscan2
- TUBA3C | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV67139512; called by muse, mutect2, varscan2
- UACA | c.3726C>G p.S1242R | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV59856825; called by muse, mutect2, varscan2
- UBQLN2 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57739234; called by muse, mutect2
- UGT3A1 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs201087553, COSV57099475, COSV57100321; called by muse, mutect2, varscan2
- VAV1 | c.2392C>T p.R798* | Nonsense Mutation (SNP) | VAF 29/102 reads (28%) | catalogued as rs1478549387, COSV58386302; called by muse, mutect2, varscan2
- WNT2 | c.326C>A p.A109D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55411854; called by muse, mutect2, varscan2
- LRP1 | c.9546_9568del p.I3183Afs*11 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel
- MTERF2 | c.934_935insAT p.S312Yfs*3 | Frame Shift Ins (INS) | VAF 22/191 reads (12%) | called by mutect2, pindel, varscan2
- NF1 | c.5430dup p.T1811Hfs*8 (on ENST00000358273 / NM_001042492.3; = p.T1790Hfs*8 on NM_000267.3) | Frame Shift Ins (INS) | VAF 43/152 reads (28%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1759_1761del p.K587del (on ENST00000521381 / NM_181523.3; = p.K317del on NM_181504.4) | In Frame Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1986-12_1992del p.X662_splice (on ENST00000521381 / NM_181523.3; = p.X392_splice on NM_181504.4) | Splice Site (DEL) | VAF 21/105 reads (20%) | called by mutect2, pindel, varscan2
- RBM15B | c.1019_1020insA p.F340Lfs*4 | Frame Shift Ins (INS) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- TLR3 | c.968del p.N323Mfs*2 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | called by mutect2, pindel, varscan2
- ZSCAN22 | c.1448del p.L483Cfs*18 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- BMX | c.36C>G p.L12= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as COSV59591967; called by muse, mutect2
- CPN2 | c.1380C>T p.D460= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as rs369348669, COSV60470118; called by muse, mutect2, varscan2
- CTAGE1 | c.1164C>T p.D388= | Silent (SNP) | VAF 34/179 reads (19%) | catalogued as rs773483618, COSV66942802; called by muse, mutect2, varscan2
- ETHE1 | c.396C>T p.S132= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV52678004; called by muse, mutect2, varscan2
- FHDC1 | c.690C>T p.G230= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as rs751935867, COSV52598757; called by muse, mutect2, varscan2
- FLNA | c.2064C>T p.A688= | Silent (SNP) | VAF 53/172 reads (31%) | catalogued as rs782738252, COSV61045865; called by muse, mutect2, varscan2
- FRAS1 | c.1737T>G p.T579= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as COSV53621550; called by muse, mutect2, varscan2
- KCNE5 | c.171C>T p.D57= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV64508475; called by muse, mutect2, varscan2
- KLK8 | c.276T>C p.D92= | Silent (SNP) | VAF 51/230 reads (22%) | catalogued as COSV51592884; called by muse, mutect2, varscan2
- LMNTD2 | c.906G>A p.P302= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs772876919, COSV54243026; called by muse, mutect2
- MUC5AC | c.645C>T p.N215= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as rs780428239, COSV62254411; called by muse, mutect2, varscan2
- MXRA5 | c.7635C>T p.H2545= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1463766438, COSV99478912; called by muse, mutect2, varscan2
- OR2L13 | c.858C>A p.P286= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV63555245; called by muse, mutect2, varscan2
- PCDHAC1 | c.1038G>A p.S346= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as rs782236455, COSV53842942; called by muse, mutect2
- PCDHGB5 | c.402G>A p.T134= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs375949491, COSV53972604; called by muse, mutect2, varscan2
- PLXNA4 | c.3615C>T p.N1205= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV58136758; called by muse, mutect2, varscan2
- PTPN3 | c.564C>T p.V188= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as rs148263399; called by muse, mutect2, varscan2
- SLC1A3 | c.768G>C p.V256= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV54315403, COSV54317724; called by muse, varscan2
- SLC25A42 | c.66G>T p.S22= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV59380691; called by muse, mutect2, varscan2
- SLC39A3 | c.381G>A p.V127= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV54118392; called by muse, mutect2, varscan2
- TATDN2 | c.594G>A p.S198= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs376639930; called by muse, mutect2, varscan2
- TECTA | c.1833C>T p.P611= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs767206817, COSV50730702; called by muse, mutect2, varscan2
- TECTA | c.4920G>A p.P1640= | Silent (SNP) | VAF 72/217 reads (33%) | catalogued as rs560030286, COSV50730822; called by muse, mutect2, varscan2
- THEM5 | c.501C>T p.D167= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs372391484; called by muse, mutect2, varscan2
- TTC30A | c.1632C>T p.C544= | Silent (SNP) | VAF 99/337 reads (29%) | catalogued as rs150534803; called by muse, mutect2, varscan2
- UGT1A4 | c.780C>T p.D260= | Silent (SNP) | VAF 96/333 reads (29%) | catalogued as rs1250192329, COSV59391845; called by muse, mutect2, varscan2
- ZNF638 | c.183T>C p.Y61= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as rs767009161, COSV52490262; called by muse, mutect2, varscan2
- DLG3 | c.1773+879C>G | Intron (SNP) | VAF 9/17 reads (53%) | catalogued as COSV99530026; called by muse, mutect2, varscan2
- SENP1 | c.221-309G>A | Intron (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99137139; called by muse, mutect2, varscan2
- SLC35A3 | c.*76A>C | 3'UTR (SNP) | VAF 21/91 reads (23%) | catalogued as rs1318351926, COSV63379332; called by muse, mutect2, varscan2
